Somatic mutation profile of tumor specimen 0DPUTO from CCDI case PBCEIS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,257 days).
Specimen 0DPUTO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbecfd0b-338a-4498-b9b2-2a041914f1e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPUTJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f28ad0f-d38a-44ce-b85b-100468b3bdf4

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Intron 4, Frame Shift Del 2, Splice Site 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 177/202 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADORA1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 228/483 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs770382721, COSV55141351; called by muse, mutect2, varscan2
- CCDC180 | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 165/347 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs140650703; called by muse, mutect2, varscan2
- GIGYF1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 274/676 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771986611, COSV51941211; called by muse, mutect2, varscan2
- PACSIN1 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 261/552 reads (47%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.985); catalogued as COSV55061808; called by muse, mutect2, varscan2
- PANX2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 272/562 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs56398924; called by muse, mutect2, varscan2
- RFPL4A | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 93/523 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs777645016, COSV70455635, COSV70455694; called by muse, mutect2
- SLC25A15 | c.317A>C p.D106A | Missense Mutation (SNP) | VAF 146/328 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.03); catalogued as COSV100090886; called by muse, varscan2
- ZFPM1 | c.2273del p.P758Rfs*40 | Frame Shift Del (DEL) | VAF 111/152 reads (73%) | catalogued as rs984199988; called by mutect2, varscan2
- ADGRG7 | c.695C>A p.T232K | Missense Mutation (SNP) | VAF 211/473 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AMER3 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 150/472 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- AP2A1 | c.2534+1G>C p.X845_splice | Splice Site (SNP) | VAF 10/275 reads (4%) | called by muse, mutect2
- ARHGAP29 | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 19/457 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASXL1 | c.817T>A p.F273I | Missense Mutation (SNP) | VAF 119/660 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CC2D2B | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 131/296 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC82 | c.529A>C p.I177L | Missense Mutation (SNP) | VAF 48/729 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2
- CFAP46 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 21/749 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2
- DEPDC5 | c.411_413+8del p.X137_splice | Splice Site (DEL) | VAF 104/118 reads (88%) | called by mutect2, varscan2
- FRY | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 219/510 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSPD1 | c.1609T>C p.S537P | Missense Mutation (SNP) | VAF 119/319 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- NBEAL2 | c.7418_7421dup p.F2475Afs*30 | Frame Shift Ins (INS) | VAF 280/568 reads (49%) | called by mutect2, varscan2
- OR2AE1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 157/315 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2T2 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- P4HA2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.027); called by muse, mutect2
- PATL1 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLCL2 | c.2030C>G p.P677R (on ENST00000615277 / NM_001144382.2; = p.P551R on NM_015184.5) | Missense Mutation (SNP) | VAF 19/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNLIP | c.1007del p.N336Mfs*9 | Frame Shift Del (DEL) | VAF 164/408 reads (40%) | called by mutect2, varscan2
- PRKAR2B | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM27 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SNX33 | c.1421T>G p.L474R | Missense Mutation (SNP) | VAF 218/681 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TLR5 | c.910A>G p.N304D | Missense Mutation (SNP) | VAF 31/632 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- TRIM22 | c.520A>G p.N174D | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF333 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 118/260 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- APOOL | c.615C>T p.S205= | Silent (SNP) | VAF 159/375 reads (42%) | catalogued as rs374210132; called by muse, mutect2, varscan2
- C4orf54 | c.1458C>T p.G486= | Silent (SNP) | VAF 146/306 reads (48%) | called by muse, mutect2, varscan2
- CYP11B2 | c.1323G>A p.V441= | Silent (SNP) | VAF 272/615 reads (44%) | catalogued as rs1477950745; called by muse, mutect2, varscan2
- GRIPAP1 | c.2154A>C p.T718= | Silent (SNP) | VAF 44/1000 reads (4%) | called by muse, mutect2
- H2BC10 | c.321G>A p.L107= | Silent (SNP) | VAF 18/340 reads (5%) | called by muse, mutect2
- OR2W3 | c.67C>T p.L23= | Silent (SNP) | VAF 218/453 reads (48%) | called by muse, mutect2, varscan2
- ZNHIT2 | c.1167C>T p.P389= | Silent (SNP) | VAF 172/395 reads (44%) | catalogued as rs767903789; called by muse, mutect2
- ADAMTS10 | c.1588-57G>C | Intron (SNP) | VAF 115/250 reads (46%) | called by muse, mutect2, varscan2
- MAP3K19 | c.*47G>A | 3'UTR (SNP) | VAF 120/374 reads (32%) | called by muse, mutect2, varscan2
- PLPP2 | c.52+218G>T | Intron (SNP) | VAF 29/268 reads (11%) | catalogued as rs945983830; called by muse, mutect2
- PORCN | c.373+32C>T | Intron (SNP) | VAF 90/193 reads (47%) | catalogued as COSV58227166; called by muse, mutect2, varscan2
- SULT1C2 | c.376-84C>A | Intron (SNP) | VAF 98/102 reads (96%) | called by muse, mutect2, varscan2
